Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO0, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAO0-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY TISSUE REPORT

ICD-O-3

Seminoma NOS 9061/3
Site: R Testis NOS C62.9

W 3/31/14

specimen Source:
Gross Exam Date:
Physician:

Pager No.:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA WITH NUMEROUS TROPHOBLASTIC ELEMENTS, right testicle and cord, radical orchiectomy. (See note)
2. EVIDENCE OF POSSIBLE LYMPHOVASCULAR INVASION IN THE SPERMATIC CORD AT THE RESECTION MARGIN.
3. INTRATUBULAR GERM CELL NEOPLASIA AND SEMINIFEROUS TUBULE ATROPHY.
4. NO INVASION OF EPIDIDYMIS NOTED.

Note: Tumor positive for c-Kit and negative for CD30. CAM 5.2 reveals numerous trophoblastic elements. HCG stain and stains to confirm the lymphovascular invasion and for purpose of staging pending.

GROSS DESCRIPTION:

The specimen received in one part in formalin labeled with the patient's name, hospital record number and "right testicle and cord". The specimen consists of a 190 grams orchectomy specimen including 10x6.5x4.5 cm testis, 2x1x1 cm epididymis and 11 cm in length and 2 cm in diameter spermatic cord. The tunica vaginalis has been opened and the testis has been previously bisected. Directly adjacent to the base of the epididymis and the base of the tunica albuginea, there is a testicular mass that appears to have replaced the entire testicle. It measures 9.5x6x6 cm and is made up of white-tan, fleshy multi-lobular, well-circumscribed mass with focal areas of hemorrhage and necrosis. There is no gross involvement of the tunica albuginea or impingement on the epididymis. The rim of testicular parenchyma at the edge of the tumor is compressed and grossly unremarkable. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable.

SUMMARY OF CASSETTES:

Cassette #1 - spermatic cord resection margin.

IN FT. ☐ COST CODE	CLINIC/WARD/NURSING STATION	PATIENT IDENTIFICATION PATIENT NAME
---	-----------------------------	--

SURGICAL PATHOLOGY TISSUE REPORT

[page 2 of 2]
SURGICAL PATHOLOGY TISSUE REPORT

- Gross Exam Date:

- Physician:

Pager No.:

Cassette #2 - tumor.
Cassette #3 - spermatic cord mid-portion.
Cassette #4 - spermatic cord and paratesticular portion.
Cassette #5 - tumor, tunica vaginalis, and epididymis.
Cassette #6 - tumor and adjacent testis.
Cassettes #7, #8, #9, #10 and #11 - representative sections of tumor.
R11.

IN PT. ☐ COST CODE	CLINIC/WARD/NURSING STATION
---	-----------------------------

SURGICAL PATHOLOGY TISSUE REPORT

PAGE 2

Source: NCI Genomic Data Commons file 63192639-a7d5-4366-a635-ddfeec94d805 (TCGA-XE-AAO0-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).